Surgical pathology report (de-identified scan), TCGA case TCGA-3B-A9HU, project TCGA-SARC (Sarcoma), tissue source site Moffitt Cancer Center, specimen TCGA-3B-A9HU-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Final Diagnosis

- A. RETROPERITONEAL MASS WITH EN BLOC RESECTION OF DUODENUM AND COLONIC MESENTERY:
Leiomyosarcoma, high grade.
Tumor size: 7.9 cm X 7.4 X 7.1 cm
Mitotic rate: 5-6/10 hpf
Necrosis: Present, about 10%
Margins:
Proximal bowel margin: Uninvolved by tumor
Distal bowel margin: Uninvolved by tumor
Soft tissue margins are free of tumor (including anterior, posterior, distal and Proximal).
Tumor is 0.1 mm from proximal soft tissue margin and 0.2 mm from distal soft tissue margin.
- B. PROXIMAL GONADAL VEIN, EXCISION:
Endothelial-lined space with muscular wall, consistent with vein, negative for malignancy.

This case was reviewed prospectively at the

I, , the attending pathologist, personally reviewed all slides and / or materials and rendered the final diagnosis. Electronically Signed Out by

Ancillary Studies

Immunohistochemistry stains, performed with adequate controls on blocks A8 and A12, revealed the tumor cells to be positive for Actin, Desmin (focally, weakly), and negative for CD34, and DOG-1. Ki-67 immunostain revealed a proliferation index of about 90%.

Key Pathological Findings

Procedure: Radical resection duodenum and colonic mesentery.
Tumor site: Retroperitoneum.
Tumor size: 7.9 cm X 7.4 X 7.1 cm
Mitotic rate: 5-6/10 HPF
Necrosis: Present, about 10%
Histologic grade:
Margins:

Proximal bowel margin: Uninvolved with tumor
Distal bowel margin: Uninvolved by tumor
Radial margin of resection: Uninvolved by tumor

ICD-O-3
Leiomyosarcoma NOS
8896/3
Retroperitoneum c48.0
JW 4/22/14

Specimen(s) Received

- A RADICAL RESECTION RETROPERITONEAL LEIOMYOSARCOMA WITH EN BLOC

[page 2 of 2]
B RESECTION OF DUODENUM, COLONIC MESENTERY
PROXIMAL GONADAL VEIN

Clinical History

Abdominal mass.

Preoperative Diagnosis

Leiomyosarcoma.

Gross Description

A. The specimen is received fresh labeled "retroperitoneal mass with en bloc resection of duodenum and colonic mesentery" and consists of a 7.9 x 7.4 x 7.1 cm, ovoid, smooth-to-shaggy, purple-gray, firm nodule with an overlying 3.1 x 3.0 cm portion of bowel wall, which is covered by granular tan mucosa. There is a small amount of attached fat. Sectioning through the nodule reveals a thinly encapsulated, lobulated, glistening, tan-gray surface with minimal congestion and less than 10% necrosis. The nodule is adherent to the overlying small bowel serosa. The anterior mucosal margin is inked green, posterior orange, proximal black, and distal blue. Representative sections are submitted as labeled:

A1-A3: Nodule to anterior and posterior small bowel margins.
A4-A5: Nodule to proximal small bowel margin.
A6-A7: Nodule to distal small bowel margin.
A8: Nodule at proximal soft tissue margin.
A9: Nodule at distal soft tissue margin.
A10: Nodule at anterior soft tissue margin.
A11: Nodule at posterior soft tissue margin with attached fat.
A12-A14: Nodule.
A15: Necrosis.

B. The specimen is received fresh labeled "proximal gonadal vein and consists of a 0.6 cm, tan-gray soft tissue, which is submitted in toto labeled B1.

Tissue from specimen A is submitted to

Source: NCI Genomic Data Commons file 3070bf98-a5b3-404a-8aa5-b55d2f1a7408 (TCGA-3B-A9HU.BBACF3CE-0B06-4B60-A966-D26D576C917E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).